Somatic mutation profile of tumor specimen 0E1BNS from CCDI case PBCVTA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1BNS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d37d4ea-6a68-49d4-82fd-3685d777d77b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1BOB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a75910e4-6fdc-46ef-a901-e91adcd5bbf9

The open-access MAF lists 36 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, Intron 4, 3'UTR 3, RNA 1, 5'UTR 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5437G>C p.E1813Q | Missense Mutation (SNP) | VAF 341/575 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as CM160050, COSV58615431, COSV58617855; called by muse, mutect2, varscan2
- ACADVL | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 211/460 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs752121435, COSV50036416; called by muse, mutect2, varscan2
- ARMC4 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 144/358 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV99519164; called by muse, mutect2, varscan2
- CFAP58 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 226/562 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.346); catalogued as rs1333758004; called by muse, varscan2
- CHST8 | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 96/201 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV52860264; called by muse, mutect2, varscan2
- LIPT1 | c.192C>G p.F64L | Missense Mutation (SNP) | VAF 177/408 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60739550; called by muse, mutect2, varscan2
- NFKB2 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 202/466 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs774802098, COSV51871057; called by muse, mutect2, varscan2
- OR13C5 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 224/554 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.33); catalogued as COSV66165185; called by muse, mutect2, varscan2
- PCDHGB2 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 136/329 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV53917629; called by muse, mutect2, varscan2
- TRHDE | c.1901A>G p.N634S | Missense Mutation (SNP) | VAF 85/318 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as rs747965814; called by muse, mutect2, varscan2
- CFAP58 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 299/694 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CYP51A1 | c.118T>A p.C40S | Missense Mutation (SNP) | VAF 126/296 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DICER1 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 216/648 reads (33%) | called by muse, mutect2, varscan2
- MUC3A | c.6059C>G p.S2020C | Missense Mutation (SNP) | VAF 109/317 reads (34%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- PSMC2 | c.816C>G p.I272M | Missense Mutation (SNP) | VAF 202/504 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- PTPRM | c.462_463del p.F154Lfs*6 | Frame Shift Del (DEL) | VAF 187/384 reads (49%) | called by mutect2, pindel, varscan2
- RBM20 | c.3166G>A p.A1056T | Missense Mutation (SNP) | VAF 104/223 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- SLC25A37 | c.51G>A p.M17I | Missense Mutation (SNP) | VAF 113/319 reads (35%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TAL1 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- THBD | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 83/158 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ABCB6 | c.1401C>T p.N467= | Silent (SNP) | VAF 175/411 reads (43%) | catalogued as rs148899972; called by muse, mutect2, varscan2
- ABCG1 | c.1467G>A p.L489= | Silent (SNP) | VAF 240/539 reads (45%) | catalogued as rs1279190693, COSV100493748; called by muse, mutect2, varscan2
- ARL6IP4 | c.216C>T p.G72= | Silent (SNP) | VAF 60/229 reads (26%) | catalogued as rs571246576; called by muse, mutect2, varscan2
- HELB | c.12G>C p.S4= | Silent (SNP) | VAF 304/492 reads (62%) | called by muse, mutect2
- LTN1 | c.2388C>T p.I796= | Silent (SNP) | VAF 150/378 reads (40%) | catalogued as COSV63734576; called by muse, mutect2, varscan2
- RHBDF2 | c.2145G>T p.R715= | Silent (SNP) | VAF 150/326 reads (46%) | called by mutect2, varscan2
- TUFM | c.672C>T p.L224= | Silent (SNP) | VAF 194/429 reads (45%) | called by muse, mutect2, varscan2
- B3GLCT | c.-39C>T | 5'UTR (SNP) | VAF 23/42 reads (55%) | called by mutect2, varscan2
- BRF1 | c.544+3227G>C | Intron (SNP) | VAF 83/144 reads (58%) | called by muse, mutect2, varscan2
- C9orf106 | n.404G>A | RNA (SNP) | VAF 105/208 reads (50%) | catalogued as rs1036228949; called by muse, mutect2, varscan2
- HADH | c.637-91C>T | Intron (SNP) | VAF 26/78 reads (33%) | called by mutect2, varscan2
- MSANTD2 | c.*81G>C | 3'UTR (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- PHACTR1 | c.1448-96G>C | Intron (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- SEPTIN8 | c.*1004C>T | 3'UTR (SNP) | VAF 137/342 reads (40%) | catalogued as rs188881056; called by muse, mutect2, varscan2
- SRRM1 | c.*49C>G | 3'UTR (SNP) | VAF 43/110 reads (39%) | called by muse, mutect2, varscan2
- TUBGCP6 | c.4315+68C>T | Intron (SNP) | VAF 51/111 reads (46%) | called by muse, mutect2, varscan2
